Surgical pathology report (de-identified scan), TCGA case TCGA-61-2614, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site University of Pittsburgh, specimen TCGA-61-2614-01A (Primary Tumor).

FINAL DIAGNOSIS:

PART 1: OMENTUM, OMENTECTOMY –
HIGH GRADE POORLY DIFFERENTIATED CARCINOMA.

PART 2: ADDITIONAL OMENTUM, EXCISION –
A. FOCAL HIGH GRADE POORLY DIFFERENTIATED CARCINOMA.
B. THREE LYMPH NODES, NEGATIVE FOR TUMOR (0 OUT OF 3).

PART 3
AND 4: LEFT AND RIGHT PELVIC SIDEWALL, BIOPSY –
HIGH GRADE POORLY DIFFERENTIATED CARCINOMA.

PART 5: UTERUS, CERVIX, BILATERAL ADNEXA, RECTOSIGMOID COLON AND APPENDIX, TOTAL ABDOMINAL
HYSTERECTOMY, BILATERAL SALPINGOOPHORECTOMY, RECTOSIGMOIDECTOMY AND APPENDECTOMY –
A. HIGH GRADE POORLY DIFFERENTIATED CARCINOMA INVOLVING RIGHT AND LEFT OVARY, EXTENDING
TO RIGHT PARATUBAL TISSUE, INFILTRATING APPENDICEAL WALL AND MESOAPPENDIX AND INVADING
FULL THICKNESS OF RECTOSIGMOID COLON.
B. SEROSA OF PROXIMAL RECTOSIGMOID MARGIN POSITIVE FOR TUMOR.
C. MYOMETRIUM AND UTERINE SEROSA WITH METASTATIC HIGH GRADE POORLY DIFFERENTIATED
CARCINOMA WITH LYMPHOVASCULAR INVASION.
D. BENIGN ENDOCERVIX.
E. ATROPHIC ENDOMETRIUM.

PART 6: RECTOSIGMOID MESENTERY, EXCISION –
HIGH GRADE POORLY DIFFERENTIATED CARCINOMA.

PART 7: BLADDER PERITONEUM, EXCISION –
HIGH GRADE POORLY DIFFERENTIATED CARCINOMA.

PART 8: LEFT IP LIGAMENT, EXCISION –
HIGH GRADE POORLY DIFFERENTIATED CARCINOMA.

PART 9: RIGHT PERIAORTIC LYMPH NODES, DISSECTION –
THREE LYMPH NODES POSITIVE FOR TUMOR (0/3).

PART 10: ANASTOMOTIC RING, EXCISION –
BOWEL WALL WITH MILD CHRONIC INFLAMMATION AND EDEMA.

CASE SYNOPSIS:

SYNOPTIC - PRIMARY OVARIAN TUMORS INCLUDING BORDERLINE TUMORS

TUMOR LOCATION:

Bilateral

PROCEDURE:

Other: appendectomy, rectosigmoidectomy, omentectomy

TUMOR SIZE:

Maximum dimension: 5.0 cm

TUMOR TYPE:

Papillary serous carcinoma

HISTOLOGIC SILVERBERG GRADE:

Poorly differentiated (8-9 pts)

ARCHITECTURAL PATTERN:

Solid (3)

CYTOLOGIC ATYPIA:

Marked (3)

MITOTIC COUNTS / 10hpf:

> or = 25 (3)

VASCULAR INVASION:

Yes

TUMOR CAPSULE:

Ruptured

SURFACE IMPLANTS:

Invasive

SURFACE IMPLANT SITE:

Uterus, Fallopian Tubes, Omentum, Peritoneal metastasis beyond the pelvis

SURFACE IMPLANT SIZE:

> 2 cm.

MALIGNANT CELLS IN ASCITES OR

PERITONEAL WASHING:

Yes

LYMPH NODES EXAMINED:

Total number of lymph nodes examined: 6

LYMPH NODES POSITIVE:

Number of positive lymph nodes, Right: 3

Number of positive lymph nodes, Left: 0

T STAGE, PATHOLOGIC:

pT3

N STAGE, PATHOLOGIC:

pN1

M STAGE, PATHOLOGIC:

pMX

FIGO STAGE:

IIIC

Source: NCI Genomic Data Commons file ca28a599-79ed-4ef6-a43d-14929f7b6392 (TCGA-61-2614.D0FFE1E5-5B41-4DFB-B82D-DA937B5B345B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).